Somatic mutation profile of tumor specimen MP2PRT-PATEMU-TMP1-A (aliquot MP2PRT-PATEMU-TMP1-A-1-0-D-A81Y-36) from MP2PRT case MP2PRT-PATEMU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.5 years (1,631 days).
Specimen MP2PRT-PATEMU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9ae42a3c-803b-46e6-ae75-26e63501ae28.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATEMU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATEMU-NB1-A-1-0-D-A81Y-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b993d302-cab6-4e95-99bb-834508ca6fbf

The open-access MAF lists 10 somatic variants for this specimen: 10 protein-altering or splice-affecting.
By variant classification: Missense Mutation 8, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 55/327 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs121913255, COSV54736320, COSV54736991, COSV54744813; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- H4C6 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 57/374 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.655); catalogued as rs747622981, COSV100897505; called by muse, mutect2, varscan2
- HIF1A | c.1248C>T p.N416= | Splice Region (SNP) | VAF 33/221 reads (15%) | catalogued as rs752454260, COSV60190187; called by muse, mutect2, varscan2
- MYH14 | c.2444G>A p.R815Q | Missense Mutation (SNP) | VAF 53/232 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs761967521, COSV51828157; called by muse, mutect2, varscan2
- NAA25 | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 57/284 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as rs766655776; called by muse, mutect2, varscan2
- PUS3 | c.1403C>T p.T468M | Missense Mutation (SNP) | VAF 38/199 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs1049344734, COSV57103106; called by muse, mutect2, varscan2
- CLDN5 | c.560T>C p.V187A (on ENST00000618236 / NM_001363066.2; = p.V272A on NM_003277.4) | Missense Mutation (SNP) | VAF 115/511 reads (23%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- RPA4 | c.537T>G p.S179R | Missense Mutation (SNP) | VAF 81/573 reads (14%) | SIFT tolerated (0.69); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- TRANK1 | c.3988_3997del p.K1330Gfs*74 | Frame Shift Del (DEL) | VAF 67/275 reads (24%) | called by mutect2, pindel, varscan2
- ZNF157 | c.841A>G p.K281E | Missense Mutation (SNP) | VAF 99/588 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
